Gene-level copy-number profile of tumor specimen C3N-04273-01 (profiled together with C3N-04273-03) from CPTAC case C3N-04273, project CPTAC-3 (Oropharynx — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Oropharynx, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 73.6 years (26,874 days).
Specimen C3N-04273-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Oropharynx; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 00af603d-1b51-43e7-81ee-4a50bcc0db87.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-04273-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,759 have no estimate.
https://portal.gdc.cancer.gov/files/c008fb42-8057-4372-9f8a-34326aa33571

Most common (modal) total copy number across autosomal genes: 5 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 439; copy number 1: 10; copy number 2: 1,072; copy number 3: 18,848; copy number 4: 2,132; copy number 5: 18,993; copy number 6: 7,545; copy number 7: 2,980; copy number 8: 3,984; copy number 9: 642; copy number 10: 1,007; copy number 11: 11; copy number 12: 36; copy number 13: 118; copy number 14: 9; copy number 15: 186; copy number 16: 391; copy number 19: 5; copy number 23: 34; copy number 24: 36; copy number 26: 265; copy number 27: 118; copy number 50: 3.

Homozygous deletions (total copy number 0; autosomes only): 25 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:196,774,813–196,795,407, 1 gene: CFHR3.
- chr4:9,153,296–9,231,233, 8 genes: FAM86KP, ALG1L14P, FAM90A26, USP17L10, USP17L11, USP17L12, USP17L13, USP17L14P.
- chr4:9,239,130–9,240,722, 1 gene (within-gene range 0–3): USP17L16P.
- chr4:68,537,184–68,670,652, 5 genes (within-gene range 0–3): UGT2B17, AC147055.2, AC147055.4, AC147055.3, UGT2B15.
- chr9:61,190,003–61,642,494, 10 genes: SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P, AL935212.3, FAM242D, Y_RNA.

Amplified relative to the modal value (total copy number ≥ 11, i.e. more than twice the modal value of 5; autosomes only): 1,212 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:11,869–133,723, 11 genes, copy number 11 (within-gene range 3–11): DDX11L1, WASH7P, MIR6859-1, MIR1302-2HG, MIR1302-2, FAM138A, OR4G4P, OR4G11P, OR4F5, AL627309.1, AL627309.3.
- chr3:88,317,156–89,590,097, 10 genes, copy number 14–19: ABCF2P1, CSNKA2IP, Y_RNA, NDUFA5P5, ICE2P2, GAPDHP50, EPHA3, AC109129.1, MTCO2P6, MTCO1P6.
- chr5:58,198–45,895,970, 679 genes, copy number 13–16 (broad region; genes not listed).
- chr6:134,169,246–134,318,112, 1 gene, copy number 13 (within-gene range 6–13): SGK1.
- chr6:134,257,035–134,950,115, 15 genes, copy number 13: RNA5SP218, Y_RNA, AL355881.1, KRT8P42, LINC01010, CHCHD2P4, CT69, AL078590.2, FAM8A6P, AL078590.1, AL596188.1, AL121970.1, MEMO1P2, ALDH8A1, AL445190.1.
- chr9:64,810,865–64,889,063, 4 genes, copy number 14: BNIP3P4, AL359955.1, AC125634.1, RNU6-1293P.
- chr18:28,638,714–29,361,963, 6 genes, copy number 12: AC090365.1, ARIH2P1, AC023932.1, RNU6-408P, AC105245.1, AC074237.1.
- chr19:27,638,483–40,122,168, 456 genes, copy number 23–50 (broad region; genes not listed).
- chr21:7,744,962–8,761,335, 30 genes, copy number 12: SMIM11B, FAM243B, SMIM34B, KCNE1B, CU633980.1, FP671120.5, FP671120.4, MIR6724-1, FP671120.1, MIR3648-1, FP671120.2, FP671120.6, RNA5-8SN2, MIR6724-2, FP671120.3, FP671120.7, 5_8S_rRNA, FP236383.3, MIR6724-3, FP236383.1, FP236383.4, RNA5-8SN3, MIR6724-4, FP236383.2, FP236383.5, RNA5-8SN1, RPSAP68, CR381572.2, CR381572.1, LINC01666.

Autosomal genes at a single copy (total copy number 1): 10. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
